Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8340, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8340-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:

Pt with 10 cm right renal mass.

Specimens Submitted:

- 1: Kidney, adrenal, peri-hilar node, right; total nephrectomy
- 2: Lymph node, retroperitoneal; excision

DIAGNOSIS:

1. Kidney, adrenal, peri-hilar node, right; total nephrectomy:

Tumor Type:

Renal cell carcinoma - Chromophobe type

Tumor Size:

Greatest diameter is 9.5 cm.

Local Invasion (for renal cortical types):

Extends into renal pelvis

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not involved

Lymph Nodes:

Free of tumor

Number of nodes examined:2

Staging for renal cell carcinoma/oncocytoma:

pT2 Tumor >7.0 cm in greatest dimension limited to the kidney

2. Lymph node, retroperitoneal; excision:

Lymph Nodes:

Not involved

Number of nodes examined:13

[page 2 of 3]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** R

Special Studies:

Result	Special Stain	Comment
	RECUT	

Gross Description:

1). The specimen is received fresh, labeled "Right kidney, Perihilar node en bloc, and right adrenal" and consists of a total nephrectomy specimen with attached perinephric fat, renal vessels, ureter, adrenal gland and perihilar nodes weighing 1098 g post fixation. The kidney measures 16.3 x 12.5 x 7.9 cm. The attached ureter measures 9.4 cm in length and 0.3 cm in diameter. The adrenal gland measures 5.3 x 1.4 x 1.1 cm. The ureter and vessel margins are identified, and appear pink tan-pink and grossly uninvolved by tumor. In the area of the hilum, few loosely attached possible lymph nodes are identified ranging in size from 0.4 to 1.4 cm in greatest dimension. The capsular surface of the kidney is pink-tan and smooth, and appears grossly uninterrupted. The specimen is bisected to reveal a well-circumscribed pseudoencapsulated red-tan focally hemorrhagic soft tumor mass measuring 9.5 x 8.9 x 7.8 cm, occupying the superior and mid pole of the kidney. The mass extends to but does not appear to grossly involve the renal pelvis. On cut section, roughly at the center of the tumor mass, an ill-defined paler white tan finely granular and slightly indurated area is identified measuring 5.5 x 2.5 cm in greatest dimension with ill-defined areas of focal hemorrhage also noted. The remainder of the mass is soft tan and focally hemorrhagic with liquefactive necrotic appearing areas noted. A thin rim of focally hemorrhagic pink-tan a firm possible renal parenchyma is identified partially surrounding the tumor. Sections of the peri-nephric fatty tissue reveal an unremarkable cut surface. The ureter is opened to reveal pink-tan corrugated mucosa with no discrete abnormalities grossly noted. The inferior renal sinus is grossly unremarkable. On cut section, the adrenal gland is grossly unremarkable. At the inferior pole of the kidney, the cortical medullary junction is well delineated with a cortex measuring up to 1 cm. Further sectioning reveals a 0.8 cm smooth walled cyst at the inferior pole. The remaining renal parenchyma is pink brown and unremarkable. Representative sections of the specimen are submitted for permanent section, and photographs have been taken.

Summary of sections:

UM -ureteral margin shaved
VM-vascular margins shaved
HN -possible peri- hilar lymph nodes
RST - representative sections
TWC-tumor with capsule and perinephric fat
NK - normal kidney
NKC-normal kidney with cyst
RP - renal pelvis
A - representative adrenal gland
RS - renal sinus

2). The specimen is received in formalin, labeled "retroperitoneal lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.4 to 2.5 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes

Summary of Sections:

Part 1: Kidney, adrenal, peri-hilar node, right; total nephrectomy

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Block	Sect. Site	PCs
1	a	1
1	hn	1
1	nk	1
1	nkc	1
2	rp	2
1	rs	1
7	rst	7
1	twc	1
1	um	1
1	vm	1

Part 2: Lymph node, retroperitoneal; excision

Block	Sect. Site	PCs
4	ln	4

Source: NCI Genomic Data Commons file fe9c149d-d05e-4124-a5c3-cb791316fe61 (TCGA-KL-8340.30D105D6-26A7-4E14-A7FE-D2C3660D3D13.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).